Gene-level copy-number profile of tumor specimen ALCH-B365-TTP1-A from ALCHEMIST case ALCH-B365, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 68.2 years (24,912 days).
Specimen ALCH-B365-TTP1-A: Sample type: FFPE Scrolls; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 46db00ca-9642-492f-abab-353f8de16fce.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator ALCH-B365-NB1-A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,230 have no estimate.
https://portal.gdc.cancer.gov/files/31769380-ffe7-440e-9ef4-0862c94dc59d

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 40; copy number 1: 3,522; copy number 2: 45,166; copy number 3: 9,252; copy number 4: 386; copy number 5: 15; copy number 6: 11; copy number 9: 1.

Homozygous deletions (total copy number 0; autosomes only): 33 genes in 6 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr12:37,575,587–37,576,384, 1 gene: ZNF970P.
- chr16:89,906,157–90,002,161, 8 genes (within-gene range 0–1): AC092143.3, MC1R, AC092143.1, AC092143.2, TUBB3, DEF8, CENPBD1, AFG3L1P.
- chr19:5,891,276–5,914,707, 4 genes (within-gene range 0–2): NDUFA11, AC024592.1, AC104532.1, VMAC.
- chr19:19,512,418–19,618,693, 8 genes (within-gene range 0–2): TSSK6, NDUFA13, AC011448.1, YJEFN3, CILP2, PBX4, PHF5CP, AC002306.1.
- chr22:17,734,138–17,779,481, 3 genes: BID, MIR3198-1, LINC00528.
- chr22:36,281,280–36,507,043, 9 genes: MYH9, MIR6819, Z82215.1, FO393418.1, RPS15AP38, Y_RNA, AL022313.2, TXN2, FOXRED2.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 27 genes in 4 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr4:1,113,639–1,153,726, 4 genes, copy number 5: AC092535.4, TMED11P, AC092535.1, AC092535.2.
- chr14:18,333,726–18,596,310, 7 genes, copy number 6–9: CR383658.1, CR383658.2, BNIP3P6, CR383656.10, CR383656.7, CR383656.13, CR383656.9.
- chr14:18,614,388–18,637,421, 5 genes, copy number 6: CR383656.6, ARHGAP42P5, LINC02297, CR383656.1, CR383656.12.
- chr21:10,413,477–13,113,790, 11 genes, copy number 5: BAGE2, AF254983.1, TPTE, CYCSP41, SLC25A15P4, AF254982.1, IGHV1OR21-1, AP001464.1, ANKRD30BP2, RNU6-614P, ZNF355P.

Autosomal genes at a single copy (total copy number 1): 2,986. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
